Somatic mutation profile of tumor specimen C3N-02373-03 (aliquot CPT0176600006) from CPTAC case C3N-02373, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 67.0 years (24,460 days).
Specimen C3N-02373-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Trunk; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 99f199f1-f43d-4931-aad3-508fac8d6c29.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02373-71 (Blood Derived Normal), aliquot CPT0176700002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/42a4834e-baa9-409b-838e-9ec68fc3f5a9

The open-access MAF lists 138 somatic variants for this specimen: 96 protein-altering or splice-affecting, 36 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 85, Silent 36, Nonsense Mutation 8, Intron 6, Splice Region 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 62/302 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- AP2B1 | c.341G>C p.R114P | Missense Mutation (SNP) | VAF 31/373 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV99251500; called by muse, mutect2
- ARAP2 | c.4474C>T p.R1492C | Missense Mutation (SNP) | VAF 22/259 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.471); catalogued as rs1462336593, COSV58292999; called by muse, mutect2
- BTNL3 | c.244C>T p.R82* | Nonsense Mutation (SNP) | VAF 60/712 reads (8%) | catalogued as rs753536584; called by muse, mutect2
- CDH8 | c.1081C>T p.H361Y | Missense Mutation (SNP) | VAF 41/378 reads (11%) | SIFT tolerated (0.28); PolyPhen benign (0.036); catalogued as COSV54872935; called by muse, mutect2, varscan2
- CHSY1 | c.1684A>T p.N562Y | Missense Mutation (SNP) | VAF 96/478 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.871); catalogued as rs892627220; called by muse, mutect2, varscan2
- CIC | c.3263G>A p.G1088E | Missense Mutation (SNP) | VAF 46/462 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as rs1452309156; called by muse, mutect2, varscan2
- COL25A1 | c.1767G>A p.G589= | Splice Region (SNP) | VAF 22/280 reads (8%) | catalogued as COSV101211276; called by muse, mutect2
- CYRIA | c.438G>A p.M146I | Missense Mutation (SNP) | VAF 30/376 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.119); catalogued as COSV62866389; called by muse, mutect2
- DDX60 | c.2491C>T p.R831C | Missense Mutation (SNP) | VAF 27/237 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); catalogued as rs778806064, COSV67095443; called by muse, mutect2, varscan2
- DNAH11 | c.6152C>T p.T2051M | Missense Mutation (SNP) | VAF 62/364 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.211); catalogued as rs375341444, COSV100176783; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EXOC3L1 | c.284G>A p.G95E | Missense Mutation (SNP) | VAF 65/589 reads (11%) | SIFT tolerated (0.67); PolyPhen benign (0.001); catalogued as rs145550510, COSV52047561; called by muse, mutect2, varscan2
- FOXL3 | c.284G>A p.R95Q | Missense Mutation (SNP) | VAF 12/223 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1012520752; called by muse, mutect2
- FREM3 | c.4552G>A p.E1518K | Missense Mutation (SNP) | VAF 38/460 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs752931215; called by muse, mutect2
- HK3 | c.1486C>T p.Q496* | Nonsense Mutation (SNP) | VAF 100/575 reads (17%) | catalogued as COSV104392751; called by muse, mutect2, varscan2
- IL1RAPL1 | c.1997C>T p.S666L | Missense Mutation (SNP) | VAF 58/300 reads (19%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.007); catalogued as COSV56300657; called by muse, mutect2, varscan2
- KHDRBS2 | c.764G>A p.G255E | Missense Mutation (SNP) | VAF 22/440 reads (5%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.952); catalogued as COSV55447739; called by muse, mutect2
- KNSTRN | c.67G>A p.D23N | Missense Mutation (SNP) | VAF 84/435 reads (19%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.037); catalogued as COSV99991973, COSV99992040; called by muse, mutect2, varscan2
- MC2R | c.645G>A p.M215I | Missense Mutation (SNP) | VAF 54/501 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.065); catalogued as COSV59617261; called by muse, mutect2, varscan2
- MYO15B | c.6017C>T p.P2006L | Missense Mutation (SNP) | VAF 57/468 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.14); catalogued as rs1435201396; called by muse, mutect2, varscan2
- NNMT | c.230C>T p.S77F | Missense Mutation (SNP) | VAF 37/392 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.957); catalogued as COSV55473489; called by muse, mutect2
- PCDHB6 | c.472G>A p.D158N | Missense Mutation (SNP) | VAF 50/464 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.734); catalogued as COSV50698707; called by muse, varscan2
- POM121L2 | c.1271C>T p.T424M | Missense Mutation (SNP) | VAF 51/490 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.832); catalogued as rs1001596414, COSV66276191; called by muse, varscan2
- PRSS58 | c.620G>A p.G207E | Missense Mutation (SNP) | VAF 48/626 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs866583795, COSV73488645; called by muse, mutect2
- RAB2A | c.130G>A p.G44S | Missense Mutation (SNP) | VAF 8/194 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs976954172, COSV104391790, COSV99389377; called by muse, mutect2
- SCN2A | c.3388G>A p.E1130K | Missense Mutation (SNP) | VAF 14/194 reads (7%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.644); catalogued as rs866249673; called by muse, mutect2
- SH3BP5L | c.625C>T p.Q209* | Nonsense Mutation (SNP) | VAF 59/724 reads (8%) | catalogued as rs1406631840, COSV100822124; called by muse, mutect2
- SIPA1L1 | c.2497C>T p.P833S | Missense Mutation (SNP) | VAF 51/518 reads (10%) | SIFT tolerated (0.95); PolyPhen possibly damaging (0.607); catalogued as rs867250144, COSV62168750; called by muse, mutect2
- SRRM2 | c.5765G>A p.R1922Q | Missense Mutation (SNP) | VAF 61/511 reads (12%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.788); catalogued as rs767837093; called by muse, mutect2, varscan2
- TBX4 | c.812C>T p.S271F | Missense Mutation (SNP) | VAF 44/474 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV53609917; called by muse, mutect2
- TEP1 | c.4862C>T p.P1621L | Missense Mutation (SNP) | VAF 37/538 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs766303079, COSV52995701; called by muse, mutect2
- TRANK1 | c.4096G>A p.E1366K | Missense Mutation (SNP) | VAF 51/393 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.346); catalogued as rs1323682268; called by muse, mutect2, varscan2
- TRIM35 | c.1253C>T p.S418L | Missense Mutation (SNP) | VAF 50/626 reads (8%) | SIFT tolerated (0.24); PolyPhen benign (0.097); catalogued as rs766348852; called by muse, mutect2
- TXNDC2 | c.538C>T p.P180S (on ENST00000306084 / NM_001098529.2; = p.P113S on NM_032243.6) | Missense Mutation (SNP) | VAF 77/712 reads (11%) | SIFT tolerated (0.67); PolyPhen probably damaging (0.977); catalogued as rs754376046, COSV60152486; called by muse, varscan2
- UGT2A1 | c.1334G>A p.R445K | Missense Mutation (SNP) | VAF 32/280 reads (11%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as rs1290352066, COSV54144405; called by muse, mutect2, varscan2
- UGT2B4 | c.554G>A p.G185E | Missense Mutation (SNP) | VAF 38/395 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs893043966; called by muse, mutect2
- WNT9A | c.541G>A p.E181K | Missense Mutation (SNP) | VAF 60/540 reads (11%) | SIFT tolerated (0.61); PolyPhen benign (0.001); catalogued as COSV99688264; called by muse, mutect2, varscan2
- ZNF780A | c.1450C>T p.R484C | Missense Mutation (SNP) | VAF 52/437 reads (12%) | SIFT tolerated (0.21); PolyPhen benign (0.012); catalogued as rs527821834, COSV100574996; called by muse, mutect2, varscan2
- ADCY5 | c.1718G>A p.G573D | Missense Mutation (SNP) | VAF 48/566 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ADGRD2 | c.1802C>T p.S601F | Missense Mutation (SNP) | VAF 26/391 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- AHNAK | c.10714C>G p.L3572V | Missense Mutation (SNP) | VAF 50/447 reads (11%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.979); called by muse, varscan2
- AHNAK2 | c.13915G>A p.E4639K | Missense Mutation (SNP) | VAF 35/359 reads (10%) | SIFT tolerated (0.8); PolyPhen benign (0.007); called by muse, mutect2
- ARFGEF2 | c.4820C>T p.S1607F | Missense Mutation (SNP) | VAF 42/319 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.535); called by muse, mutect2, varscan2
- ASPHD1 | c.92C>T p.P31L | Missense Mutation (SNP) | VAF 42/566 reads (7%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); called by muse, mutect2
- ASZ1 | c.328+1G>A p.X110_splice | Splice Site (SNP) | VAF 51/255 reads (20%) | called by muse, mutect2, varscan2
- BIRC7 | c.395A>T p.Q132L | Missense Mutation (SNP) | VAF 79/597 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.918); called by muse, mutect2, varscan2
- C11orf80 | c.1495C>T p.H499Y | Missense Mutation (SNP) | VAF 82/1335 reads (6%) | SIFT tolerated (0.68); PolyPhen benign (0.011); called by muse, mutect2
- CA2 | c.538C>T p.P180S | Missense Mutation (SNP) | VAF 37/352 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- CACNG4 | c.677C>T p.S226F | Missense Mutation (SNP) | VAF 51/418 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- CEACAM6 | c.84G>A p.W28* | Nonsense Mutation (SNP) | VAF 27/314 reads (9%) | called by muse, mutect2
- CFAP47 | c.7495G>A p.D2499N | Missense Mutation (SNP) | VAF 24/109 reads (22%) | SIFT tolerated (0.97); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- COL21A1 | c.1198C>T p.Q400* | Nonsense Mutation (SNP) | VAF 30/163 reads (18%) | called by muse, mutect2, varscan2
- COL25A1 | c.1766G>A p.G589E | Missense Mutation (SNP) | VAF 22/279 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DCLK1 | c.1960G>A p.E654K | Missense Mutation (SNP) | VAF 20/308 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.018); called by muse, mutect2
- DENND4A | c.1606G>A p.D536N | Missense Mutation (SNP) | VAF 35/390 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.051); called by muse, mutect2
- DNAH9 | c.6218C>T p.S2073F | Missense Mutation (SNP) | VAF 47/634 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.514); called by muse, mutect2
- ERG | c.998A>G p.N333S (on ENST00000398919 / NM_001243428.1; = p.N309S on NM_004449.4) | Missense Mutation (SNP) | VAF 43/377 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- FAM227A | c.752C>T p.A251V | Missense Mutation (SNP) | VAF 362/638 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- FBXO40 | c.889A>G p.R297G | Missense Mutation (SNP) | VAF 57/453 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- FRMD7 | c.289C>T p.L97F | Missense Mutation (SNP) | VAF 19/138 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GPR61 | c.58C>T p.P20S | Missense Mutation (SNP) | VAF 48/496 reads (10%) | SIFT tolerated (0.5); PolyPhen benign (0.007); called by muse, mutect2
- HERPUD2 | c.820C>T p.R274* | Nonsense Mutation (SNP) | VAF 70/480 reads (15%) | called by muse, varscan2
- HTRA2 | c.1153C>T p.P385S | Missense Mutation (SNP) | VAF 27/244 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- IP6K2 | c.551A>G p.H184R | Missense Mutation (SNP) | VAF 42/480 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.036); called by muse, mutect2
- KAT6A | c.2186C>T p.S729F | Missense Mutation (SNP) | VAF 43/325 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- KCNK3 | c.1142T>G p.L381R | Missense Mutation (SNP) | VAF 75/569 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.569); called by muse, mutect2, varscan2
- KCNT2 | c.2296G>A p.D766N | Missense Mutation (SNP) | VAF 35/374 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.027); called by muse, mutect2
- KIF25 | c.385G>A p.D129N | Missense Mutation (SNP) | VAF 91/410 reads (22%) | SIFT tolerated (0.25); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- LAMB4 | c.4384G>A p.E1462K | Missense Mutation (SNP) | VAF 58/364 reads (16%) | SIFT tolerated (0.34); PolyPhen benign (0); called by muse, mutect2, varscan2
- MGAM2 | c.3798G>A p.M1266I | Missense Mutation (SNP) | VAF 28/280 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.63); called by muse, mutect2
- MIPEP | c.2096C>T p.S699F | Missense Mutation (SNP) | VAF 26/396 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.027); called by muse, mutect2
- NCAPD3 | c.4267G>A p.V1423I | Missense Mutation (SNP) | VAF 34/240 reads (14%) | SIFT tolerated (0.39); PolyPhen benign (0.077); called by muse, varscan2
- NLRC5 | c.4165C>T p.P1389S | Missense Mutation (SNP) | VAF 50/364 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.13); called by muse, varscan2
- OTOGL | c.2905G>A p.D969N (on ENST00000547103; = p.D960N on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/274 reads (7%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.757); called by muse, mutect2
- PGBD4 | c.1133T>A p.F378Y | Missense Mutation (SNP) | VAF 77/399 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.246); called by muse, mutect2, varscan2
- PIP5KL1 | c.23C>T p.P8L | Missense Mutation (SNP) | VAF 49/573 reads (9%) | SIFT tolerated, low confidence (0.12); PolyPhen possibly damaging (0.538); called by muse, mutect2
- PKD1L3 | c.3621G>A p.V1207= | Splice Region (SNP) | VAF 30/264 reads (11%) | called by muse, mutect2, varscan2
- PLCB2 | c.2132C>T p.P711L | Missense Mutation (SNP) | VAF 78/461 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); called by muse, mutect2, varscan2
- RAPGEFL1 | c.596A>T p.Q199L | Missense Mutation (SNP) | VAF 22/266 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.037); called by muse, mutect2
- RBBP8NL | c.1793A>T p.E598V | Missense Mutation (SNP) | VAF 39/482 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.035); called by muse, mutect2
- RBM33 | c.2153T>A p.V718E | Missense Mutation (SNP) | VAF 44/431 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- RFTN1 | c.874T>C p.C292R | Missense Mutation (SNP) | VAF 17/539 reads (3%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.483); called by muse, mutect2
- SCNN1B | c.742G>T p.A248S | Missense Mutation (SNP) | VAF 40/429 reads (9%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.802); called by muse, mutect2
- SLIT2 | c.3454C>T p.Q1152* | Nonsense Mutation (SNP) | VAF 26/316 reads (8%) | called by muse, mutect2
- TACR1 | c.1067C>G p.T356S | Missense Mutation (SNP) | VAF 73/595 reads (12%) | SIFT tolerated (0.27); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- TBC1D22A | c.100G>A p.D34N | Missense Mutation (SNP) | VAF 42/1543 reads (3%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.696); called by muse, mutect2
- THRAP3 | c.452C>T p.S151F | Missense Mutation (SNP) | VAF 39/469 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); called by muse, mutect2
- TLL1 | c.2164G>A p.G722S | Missense Mutation (SNP) | VAF 27/320 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TLX2 | c.811G>A p.D271N | Missense Mutation (SNP) | VAF 32/368 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0.001); called by muse, mutect2
- TMEM132C | c.635C>T p.A212V | Missense Mutation (SNP) | VAF 63/641 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0.228); called by muse, mutect2
- TNPO3 | c.2539C>T p.P847S | Missense Mutation (SNP) | VAF 42/512 reads (8%) | SIFT tolerated (0.71); PolyPhen benign (0.003); called by muse, mutect2
- TSN | c.238C>T p.P80S | Missense Mutation (SNP) | VAF 25/187 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.779); called by muse, mutect2, varscan2
- TUBA1A | c.115G>A p.D39N | Missense Mutation (SNP) | VAF 52/636 reads (8%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.006); called by muse, mutect2
- USP4 | c.1148C>T p.A383V | Missense Mutation (SNP) | VAF 30/289 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.391); called by muse, mutect2, varscan2
- ZNF384 | c.545G>A p.G182E | Missense Mutation (SNP) | VAF 49/592 reads (8%) | SIFT tolerated (0.45); PolyPhen benign (0.422); called by muse, mutect2
- ZNF681 | c.877C>T p.Q293* | Nonsense Mutation (SNP) | VAF 40/466 reads (9%) | called by muse, mutect2
- A4GALT | c.537G>A p.R179= | Silent (SNP) | VAF 182/879 reads (21%) | called by muse, mutect2, varscan2
- ACSL3 | c.1971G>A p.E657= | Silent (SNP) | VAF 37/367 reads (10%) | called by muse, mutect2, varscan2
- AHRR | c.1236C>A p.A412= | Silent (SNP) | VAF 111/2433 reads (5%) | called by muse, mutect2
- AL136295.1 | c.1353C>T p.S451= | Silent (SNP) | VAF 52/581 reads (9%) | catalogued as rs748825617; called by muse, mutect2
- AQP7 | c.840C>T p.I280= | Silent (SNP) | VAF 51/437 reads (12%) | called by muse, mutect2, varscan2
- ATP2B3 | c.675G>A p.L225= | Silent (SNP) | VAF 12/232 reads (5%) | catalogued as rs1255966339; called by muse, mutect2
- BX276092.9 | c.288G>A p.A96= | Silent (SNP) | VAF 43/220 reads (20%) | catalogued as COSV70724142; called by muse, mutect2, varscan2
- CASP10 | c.408C>T p.F136= | Silent (SNP) | VAF 43/457 reads (9%) | called by muse, mutect2
- CCDC6 | c.930G>A p.R310= | Silent (SNP) | VAF 43/407 reads (11%) | called by muse, mutect2, varscan2
- DUOX2 | c.1362G>A p.R454= | Silent (SNP) | VAF 64/447 reads (14%) | called by muse, mutect2, varscan2
- GRM2 | c.1563C>T p.L521= | Silent (SNP) | VAF 53/492 reads (11%) | catalogued as COSV56588251; called by muse, mutect2, varscan2
- HDAC10 | c.1728G>A p.L576= | Silent (SNP) | VAF 148/1722 reads (9%) | catalogued as rs1469968051; called by muse, mutect2
- HMMR | c.1845G>A p.Q615= | Silent (SNP) | VAF 40/248 reads (16%) | called by muse, mutect2, varscan2
- HPSE | c.1014G>A p.K338= | Silent (SNP) | VAF 32/326 reads (10%) | called by muse, mutect2, varscan2
- IRAG1 | c.1584C>T p.L528= | Silent (SNP) | VAF 39/348 reads (11%) | called by muse, mutect2, varscan2
- JAK2 | c.306C>T p.F102= | Silent (SNP) | VAF 24/246 reads (10%) | catalogued as COSV101074934; called by muse, mutect2
- MED1 | c.2793C>T p.F931= | Silent (SNP) | VAF 36/350 reads (10%) | catalogued as rs1567638522; called by muse, mutect2, varscan2
- MEI1 | c.537G>A p.L179= | Silent (SNP) | VAF 62/804 reads (8%) | called by muse, mutect2
- MTMR6 | c.1119C>T p.I373= | Silent (SNP) | VAF 10/210 reads (5%) | catalogued as COSV67809047; called by muse, mutect2
- MYH15 | c.4533G>A p.R1511= | Silent (SNP) | VAF 20/328 reads (6%) | catalogued as rs1466887730; called by muse, mutect2
- MYO10 | c.1485G>A p.L495= | Silent (SNP) | VAF 759/1053 reads (72%) | called by muse, mutect2, varscan2
- NOS1AP | c.1254C>T p.P418= | Silent (SNP) | VAF 60/631 reads (10%) | catalogued as COSV100723310; called by muse, mutect2
- OR1G1 | c.640C>T p.L214= | Silent (SNP) | VAF 42/383 reads (11%) | called by muse, mutect2, varscan2
- OR56A1 | c.291C>T p.F97= | Silent (SNP) | VAF 61/465 reads (13%) | called by muse, mutect2, varscan2
- PCDHB9 | c.2340G>A p.G780= | Silent (SNP) | VAF 63/382 reads (16%) | catalogued as COSV53382397; called by muse, mutect2, varscan2
- PLIN5 | c.333G>A p.S111= | Silent (SNP) | VAF 33/308 reads (11%) | catalogued as rs367964761; called by muse, mutect2, varscan2
- RRH | c.259C>T p.L87= | Silent (SNP) | VAF 39/452 reads (9%) | called by muse, mutect2
- SDR42E1 | c.75C>T p.G25= | Silent (SNP) | VAF 13/270 reads (5%) | called by muse, mutect2
- SNED1 | c.4233G>A p.E1411= | Silent (SNP) | VAF 24/409 reads (6%) | catalogued as rs1350295908; called by muse, mutect2
- SOCS4 | c.423C>T p.A141= | Silent (SNP) | VAF 33/404 reads (8%) | called by muse, mutect2
- TAS1R3 | c.1953C>T p.L651= | Silent (SNP) | VAF 60/640 reads (9%) | called by muse, mutect2
- TEP1 | c.4863C>T p.P1621= | Silent (SNP) | VAF 37/538 reads (7%) | catalogued as rs1440223463; called by muse, mutect2
- TLX2 | c.810G>A p.E270= | Silent (SNP) | VAF 32/371 reads (9%) | catalogued as rs747846381; called by muse, mutect2
- TRIM13 | c.948G>A p.K316= | Silent (SNP) | VAF 28/413 reads (7%) | catalogued as rs1291416043; called by muse, mutect2
- ZBED5 | c.1194C>T p.I398= | Silent (SNP) | VAF 13/323 reads (4%) | called by muse, mutect2
- ZNF415 | c.1398G>A p.K466= | Silent (SNP) | VAF 36/407 reads (9%) | catalogued as COSV54704802; called by muse, mutect2
- EDN3 | c.588+21C>T | Intron (SNP) | VAF 36/422 reads (9%) | catalogued as COSV100284796; called by muse, mutect2
- KCNQ1 | c.1394-16256G>A | Intron (SNP) | VAF 26/260 reads (10%) | called by muse, mutect2
- NDUFV3 | c.170-4603C>T | Intron (SNP) | VAF 41/284 reads (14%) | catalogued as rs368251445; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- OBSCN | c.18662-2899C>T | Intron (SNP) | VAF 64/628 reads (10%) | called by muse, mutect2, varscan2
- SLCO1B3-SLCO1B7 | c.1866-51545G>A | Intron (SNP) | VAF 17/181 reads (9%) | catalogued as rs1044931562, COSV67440801; called by muse, mutect2, varscan2
- UNC13B | c.762-6684C>T | Intron (SNP) | VAF 25/229 reads (11%) | called by muse, mutect2, varscan2
